Gene-level copy-number profile of tumor specimen TCGA-60-2709-01A from TCGA case TCGA-60-2709, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.7 years (25,453 days).
Specimen TCGA-60-2709-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8bd13824-1d0d-4779-94b7-335cf52dc741.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2709-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e80c3bbc-d1d9-4d79-94d7-6f6e8d58d0e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 101; copy number 1: 1,432; copy number 2: 36,105; copy number 3: 19,553; copy number 4: 1,751; copy number 5: 348; copy number 6: 34; copy number 7: 87; copy number 8: 35; copy number 9: 355; copy number 10: 7; copy number 13: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2709-01A-21D-1816-01): tumor purity 0.15, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,868,839–22,518,871, 93 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 868 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,336,446–63,827,843, 87 genes, copy number 5 (broad region; genes not listed).
- chr3:164,171,471–198,222,513, 637 genes, copy number 5–9 (broad region; genes not listed).
- chr5:12,297,399–16,465,800, 45 genes, copy number 7–10: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622.
- chr6:63,719,980–65,707,226, 1 gene, copy number 8 (within-gene range 2–13): EYS.
- chr6:64,377,795–65,789,287, 5 genes, copy number 8–13: AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1.
- chr7:98,617,285–99,735,102, 34 genes, copy number 6 (within-gene range 3–6): NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1, AC004922.1, ARPC1A, ARPC1B, PDAP1, BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394, ZKSCAN5, FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25, AC005020.1, CYP3A5, CYP3A7-CYP3A51P, CYP3A51P.
- chr8:36,764,445–38,560,939, 59 genes, copy number 5: RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1.

Autosomal genes at a single copy (total copy number 1): 1,432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
